Gene-level copy-number profile of tumor specimen ALCH-B268-TTP1-A from ALCHEMIST case ALCH-B268, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.4 years (21,681 days).
Specimen ALCH-B268-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3e10bb43-2491-45f3-92ed-844b99a1269c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B268-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,766 have no estimate.
https://portal.gdc.cancer.gov/files/9320addd-01de-4089-8863-58b959457c33

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 11,250; copy number 2: 45,211; copy number 3: 1,557; copy number 4: 636; copy number 5: 82; copy number 6: 24; copy number 7: 11; copy number 8: 11; copy number 9: 9; copy number 10: 8; copy number 11: 1; copy number 12: 4; copy number 13: 3; copy number 21: 3; copy number 32: 2.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,275,223–1,280,420, 1 gene: LINC01786.
- chr2:2,707,368–2,840,512, 1 gene (within-gene range 0–1): AC011995.2.
- chr2:90,359,809–90,367,699, 2 genes: AC233263.1, AC233263.7.
- chr2:231,433,923–231,437,421, 2 genes: ZBTB8OSP2, HIGD2AP1.
- chr3:9,919,051–9,919,153, 1 gene (within-gene range 0–1): RNU6-882P.
- chr8:311,133–384,079, 2 genes: AC136777.1, FAM87A.
- chr8:12,178,697–12,194,133, 2 genes: ALG1L11P, FAM86B1.
- chr8:12,374,366–12,375,546, 1 gene (within-gene range 0–1): AC087203.1.
- chr8:33,547,754–33,567,128, 1 gene: RNF122.
- chr8:37,962,990–37,983,373, 2 genes: ADRB3, RPL12P48.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr8:43,542,076–43,544,057, 1 gene: AC134698.2.
- chr9:36,779,475–36,830,456, 2 genes: AL450267.2, MIR4475.
- chr9:136,249,978–136,251,205, 1 gene: CR392000.1.
- chr9:136,483,495–136,486,067, 1 gene (within-gene range 0–2): C9orf163.
- chr9:137,286,112–137,287,236, 1 gene: BX255925.2.
- chr11:62,787,402–62,790,400, 2 genes (within-gene range 0–1): TMEM179B, MIR6748.
- chr12:120,941,728–120,980,965, 1 gene (within-gene range 0–2): HNF1A-AS1.
- chr14:104,376,530–104,378,951, 1 gene: AL512357.1.
- chr14:106,695,102–106,695,397, 1 gene: IGHVIII-67-4.
- chr16:1,273,751–1,276,522, 1 gene: AC120498.7.
- chr16:46,469,341–46,569,097, 2 genes: ANKRD26P1, RNU6-845P.
- chr17:82,037,905–82,039,380, 1 gene: DCXR-DT.
- chr19:9,100,407–9,107,475, 1 gene: OR7G2.
- chr19:9,265,440–9,268,819, 1 gene: OR7E19P.
- chr19:56,176,008–56,197,920, 2 genes: GALP, ZSCAN5B.
- chr21:8,759,077–8,761,335, 1 gene: LINC01666.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:20,110,821–20,117,392, 3 genes (within-gene range 0–2): AC006547.2, TRMT2A, MIR6816.
- chr22:50,738,196–50,745,339, 2 genes: ACR, AC002056.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 158 genes in 72 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,211,340–1,251,334, 5 genes, copy number 5–7: TNFRSF4, SDF4, B3GALT6, C1QTNF12, AL162741.1.
- chr1:1,308,597–1,311,677, 1 gene, copy number 9 (within-gene range 2–9): PUSL1.
- chr1:1,324,756–1,328,896, 1 gene, copy number 5: CPTP.
- chr1:1,335,276–1,361,777, 3 genes, copy number 8–12 (within-gene range 2–12): DVL1, MIR6808, MXRA8.
- chr1:1,399,520–1,402,046, 1 gene, copy number 5: MRPL20-AS1.
- chr1:1,426,128–1,434,573, 2 genes, copy number 21: TMEM88B, LINC01770.
- chr1:1,512,162–1,534,685, 1 gene, copy number 5: ATAD3A.
- chr1:2,581,560–2,591,469, 2 genes, copy number 5 (within-gene range 2–5): AL139246.3, PRXL2B.
- chr1:2,811,850–2,817,767, 3 genes, copy number 5: AL592464.2, AL592464.3, AL592464.1.
- chr3:171,815,586–172,401,669, 7 genes, copy number 5 (within-gene range 4–5): TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P.
- chr3:177,010,719–177,228,000, 5 genes, copy number 5: MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P.
- chr3:183,613,620–183,684,519, 2 genes, copy number 5–6: AC068769.1, KLHL24.
- chr3:184,812,143–185,153,060, 2 genes, copy number 5: VPS8, C3orf70.
- chr4:2,247,432–2,262,109, 2 genes, copy number 5 (within-gene range 5–6): MXD4, MIR4800.
- chr7:37,032–95,683, 3 genes, copy number 5–9 (within-gene range 4–9): AC215522.1, AC093627.1, AC093627.6.
- chr7:1,530,702–1,560,821, 2 genes, copy number 7: MAFK, TMEM184A.
- chr8:66,562,175–66,667,231, 3 genes, copy number 5: MYBL1, VCPIP1, Y_RNA.
- chr8:70,103,798–70,424,576, 5 genes, copy number 5: H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2.
- chr9:136,327,476–136,363,744, 2 genes, copy number 7 (within-gene range 2–7): GPSM1, DNLZ.
- chr9:136,844,415–136,860,799, 3 genes, copy number 10 (within-gene range 2–10): AJM1, PHPT1, MAMDC4.
- chr9:137,241,287–137,253,497, 4 genes, copy number 5–10: TUBB4B, FAM166A, STPG3-AS1, STPG3.
- chr9:137,447,570–137,459,334, 2 genes, copy number 12: NSMF, MIR7114.
- chr14:104,857,792–104,896,770, 2 genes, copy number 11–21: AL583810.1, CEP170B.
- chr14:105,093,609–105,100,131, 2 genes, copy number 32: LINC02298, AL512356.4.
- chr14:105,140,982–105,181,323, 4 genes, copy number 6–8 (within-gene range 6–22): JAG2, MIR6765, AL512356.1, NUDT14.
- chr14:105,472,962–105,499,575, 4 genes, copy number 6–8: CRIP2, CRIP1, AL928654.3, TEDC1.
- chr14:105,583,731–105,588,395, 1 gene, copy number 9: IGHA2.
- chr16:769,119–788,397, 4 genes, copy number 6–9 (within-gene range 4–9): AL031258.1, MSLNL, MIR662, RPUSD1.
- chr16:981,770–1,242,554, 17 genes, copy number 5–12: SOX8, AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1, AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10, TPSB2, TPSAB1.
- chr16:88,186,605–88,195,217, 2 genes, copy number 5: LINC02182, AC134312.6.
- chr16:88,984,032–89,052,966, 2 genes, copy number 6–8: AC135782.2, AC135782.1.
- chr17:79,792,132–79,802,529, 2 genes, copy number 5: CBX8, AC100791.2.
- chr17:81,528,377–81,553,961, 2 genes, copy number 5–7: FSCN2, FAAP100.
- chr17:82,023,305–82,037,709, 4 genes, copy number 9 (within-gene range 4–9): LRRC45, RAC3, DCXR, AC137723.1.
- chr19:33,997,289–34,066,283, 3 genes, copy number 5: AC016587.1, RPS4XP23, RPS4XP20.
- chr19:34,533,427–34,577,701, 3 genes, copy number 5: RPS26P55, ZNF807P, SCGB1B2P.
- chr19:34,734,155–34,832,869, 5 genes, copy number 5 (within-gene range 3–5): ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1.
- chr20:63,166,797–63,180,903, 2 genes, copy number 5 (within-gene range 5–18): AL096828.1, MIR124-3.
- chr20:63,343,223–63,378,401, 2 genes, copy number 13: CHRNA4, AL121827.1.
- chr20:63,528,001–63,556,695, 4 genes, copy number 5–13: PTK6, SRMS, AL121829.2, FNDC11.

Autosomal genes at a single copy (total copy number 1): 8,394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
